Somatic mutation profile of tumor specimen 0DK5H7 from CCDI case PBBXBR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.5 years (5,283 days).
Specimen 0DK5H7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eab5ce77-f7c0-48f5-b03e-98c53971152f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK5HM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74d50c35-e996-4c24-a548-df711b291815

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1841 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 60/1234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99694180; called by muse, mutect2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 29/1113 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 86/1292 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- FAP | c.1815-32A>G | Intron (SNP) | VAF 20/586 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 42/320 reads (13%) | called by muse, varscan2
- SELENOI | c.*14G>T | 3'UTR (SNP) | VAF 29/738 reads (4%) | called by muse, mutect2
